Somatic mutation profile of tumor specimen TCGA-DD-AA3A-01A (aliquot TCGA-DD-AA3A-01A-11D-A36X-10) from TCGA case TCGA-DD-AA3A, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Combined hepatocellular carcinoma and cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 81.3 years (29,712 days).
Specimen TCGA-DD-AA3A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 883b29f3-b09e-4f35-be7d-0705454eace8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AA3A-10A (Blood Derived Normal), aliquot TCGA-DD-AA3A-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22808c1c-bd0c-4e87-aeb8-5ff152f78c61

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, Frame Shift Del 5, Nonsense Mutation 2, Splice Region 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.2266A>C p.K756Q | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99710257; called by muse, mutect2, varscan2
- CALCR | c.728A>T p.Q243L (on ENST00000649521 / NM_001164737.2; = p.Q227L on NM_001742.4) | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.132); catalogued as COSV100810413; called by muse, mutect2, varscan2
- CPAMD8 | c.1500C>A p.C500* (on ENST00000651564; = p.C453* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 66/127 reads (52%) | catalogued as COSV99358991; called by muse, mutect2, varscan2
- DAO | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99948445; called by muse, mutect2, varscan2
- DLEC1 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100341502; called by muse, mutect2, varscan2
- DYRK1A | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as rs750600368, COSV100117469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENOSF1 | c.22del p.R8Gfs*22 (on ENST00000340116 / NM_001354066.2; = p.R8Gfs*34 on NM_017512.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 61/185 reads (33%) | catalogued as rs1193738262; called by mutect2, pindel, varscan2
- FSTL5 | c.1393A>G p.I465V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs771029095, COSV100052888; called by muse, mutect2
- GALNT8 | c.127A>T p.R43W | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99362500; called by muse, mutect2, varscan2
- GLB1L3 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101111006; called by muse, mutect2, varscan2
- H1-4 | c.323A>C p.N108T | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV56800749, COSV99175215; called by muse, mutect2, varscan2
- ING5 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 66/776 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV100545914; called by muse, mutect2
- INO80 | c.3163C>G p.P1055A | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.991); catalogued as COSV100731543, COSV62740244; called by muse, mutect2, varscan2
- KRT33A | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as rs755531489, COSV99144777; called by muse, mutect2, varscan2
- MINPP1 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV100916732; called by muse, mutect2, varscan2
- MMP7 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV99496946; called by muse, mutect2, varscan2
- NCKAP5L | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs369718554; called by muse, mutect2, varscan2
- NOL12 | c.84G>T p.R28= | Splice Region (SNP) | VAF 22/320 reads (7%) | catalogued as COSV100767120; called by muse, mutect2
- NUP210L | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 56/271 reads (21%) | catalogued as rs771522844, COSV55141015; called by muse, mutect2, varscan2
- PARPBP | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as rs779976676, COSV100568994; called by muse, mutect2, varscan2
- PCSK7 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1193006173, COSV100309199; called by muse, mutect2, varscan2
- RBM15 | c.191C>G p.S64W | Missense Mutation (SNP) | VAF 107/262 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV100873402; called by muse, mutect2, varscan2
- SBNO1 | c.3768G>C p.K1256N (on ENST00000420886; = p.K1255N on NM_018183.5) | Missense Mutation (SNP) | VAF 145/403 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV99928738; called by muse, mutect2, varscan2
- SMARCC2 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs764190806, COSV99910809; called by muse, mutect2, varscan2
- SNAP25 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV99654525; called by muse, mutect2, varscan2
- SPAG4 | c.76T>G p.S26A | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100958262; called by muse, mutect2, varscan2
- TCERG1 | c.1146G>T p.M382I | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV99694416; called by muse, mutect2
- TLR4 | c.2423G>T p.W808L (on ENST00000355622 / NM_138554.5; = p.W768L on NM_003266.4) | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); catalogued as COSV100842665; called by muse, mutect2, varscan2
- WDR45 | c.339C>T p.D113= (on ENST00000376372 / NM_001029896.2; = p.D114= on NM_007075.3) | Splice Region (SNP) | VAF 115/262 reads (44%) | catalogued as COSV100540101; called by muse, mutect2, varscan2
- ZBTB7C | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1039584444, COSV100134265; called by muse, mutect2, varscan2
- BAP1 | c.1260del p.K421Rfs*9 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | called by mutect2, pindel, varscan2
- CHID1 | c.1041-16_1041-1del p.X347_splice | Splice Site (DEL) | VAF 25/123 reads (20%) | called by mutect2, pindel, varscan2
- LRFN1 | c.248del p.R83Qfs*6 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel*, varscan2
- MAGIX | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PRLHR | c.615_628del p.H206Lfs*196 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- XRN1 | c.4932_4935del p.S1645Hfs*9 | Frame Shift Del (DEL) | VAF 128/168 reads (76%) | called by pindel, varscan2
- ADAM10 | c.2061T>G p.A687= | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as COSV99545561; called by muse, mutect2, varscan2
- BRINP3 | c.156A>T p.G52= | Silent (SNP) | VAF 14/385 reads (4%) | catalogued as COSV100818375; called by muse, mutect2
- DSG3 | c.427C>T p.L143= | Silent (SNP) | VAF 148/403 reads (37%) | catalogued as COSV99933771; called by muse, mutect2, varscan2
- KMT5B | c.1371T>C p.H457= | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as rs765500897, COSV100429921; called by muse, mutect2, varscan2
- LBH | c.45G>C p.S15= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as COSV101257758; called by muse, mutect2, varscan2
- LTA4H | c.1815G>A p.G605= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as rs1185617644, COSV99701196; called by muse, mutect2
- NRXN1 | c.3213C>T p.F1071= | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as COSV100453388; called by muse, mutect2, varscan2
- PAK4 | c.216G>T p.R72= | Silent (SNP) | VAF 76/185 reads (41%) | catalogued as COSV100426377; called by muse, mutect2, varscan2
- SNN | c.261C>T p.H87= | Silent (SNP) | VAF 56/146 reads (38%) | catalogued as rs1045239527, COSV99297267; called by muse, mutect2, varscan2
- SPTBN2 | c.2449C>T p.L817= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV100018261; called by muse, mutect2, varscan2
- SULF1 | c.2511A>G p.G837= | Silent (SNP) | VAF 26/401 reads (6%) | catalogued as COSV99482194; called by muse, mutect2
- ZFHX4 | c.9033C>T p.L3011= | Silent (SNP) | VAF 78/202 reads (39%) | catalogued as rs1460438408, COSV99256559; called by muse, mutect2, varscan2
- SNAP25 | c.164-172C>G | Intron (SNP) | VAF 33/142 reads (23%) | catalogued as COSV99654523; called by muse, mutect2, varscan2
